Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A40R, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A40R-01A (Primary Tumor).

Spec. Taken

7/14/12

INTERPRETATION AND DIAGNOSIS:

THYROID (TOTAL THYROIDECTOMY): ICD-O-3

SPECIMEN TYPE:

Total thyroidectomy

Carcinoma, papillary, follicular variant
8340/3

TUMOR SITE:

Left lobe

Site: Thyroid, NOS C73.9 7-18-12 RD

HISTOLOGIC TYPE:

Papillary carcinoma, follicular variant per TBS on 7/12/12, follicular variant = 99%
lw

TUMOR SIZE:

3 cm

FOCALITY:

Unifocal (with psammoma bodies scattered
in the gland)

LYMPH NODES:

Metastatic carcinoma in 7 of 20 lymph nodes

EXTENT OF INVASION (Edition AJCC):

PRIMARY TUMOR:

pT2: tumor >2 cm but <4 cm, limited to thyroid

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to level VI (pretracheal, paratracheal,
and prelaryngeal/Delphian) nodes

MARGINS:

Involved by invasive carcinoma (deep margin)

VENOUS/LYMPHATIC INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS:

Thyroiditis (lymphocytic)

NOTE: Parathyroid tissue identified (single focus). Dr. has
reviewed this case.

Source: NCI Genomic Data Commons file e2fa2e52-4877-4bb2-811a-021bd1f321a9 (TCGA-ET-A40R.16EB0191-4EEF-4425-9CBF-1B10089790D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).